MMRF case MMRF_2313 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/95e89871-bedd-4f62-97c8-f6bc08d86cb8

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.4 years (19,493 days); ISS stage: II; Days to last known disease status: 794 days (2.2 years); Days to last follow up: 794 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 340 days.
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 358 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 268 days; Days to treatment end: 268 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 743 days (2.0 years); Days to treatment end: 743 days (2.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 743 days (2.0 years); Days to treatment end: 746 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 749 days (2.1 years); Days to treatment end: 759 days (2.1 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 773 days (2.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -12 (ECOG 0): M Protein 4.01 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 345 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.101 mg/dL; Immunoglobulin G 3.21 g/L; Immunoglobulin A 44.1 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 4.29 µg/mL; Lactate Dehydrogenase 3.57 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.44 ×10⁹/L; Absolute Neutrophil 3.26 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 98.1 µmol/L; Calcium 2.35 mmol/L; Albumin 33 g/L; Total Protein 8.9 g/dL; Glucose 5.83 mmol/L; C-Reactive Protein 0.11 mg/dL.
- Day 66 (ECOG 0): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 126 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 4.01 g/L; Immunoglobulin A 14.8 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 2.35 µg/mL; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.66 ×10⁹/L; Absolute Neutrophil 1.71 ×10⁹/L; Platelets 281 ×10⁹/L; Creatinine 72.5 µmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 7.37 mmol/L.
- Day 141 (ECOG 0): M Protein 1.48 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 108 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 3.31 g/L; Immunoglobulin A 11.6 g/L; Immunoglobulin M 0.193 g/L; Beta 2 Microglobulin 2.27 µg/mL; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 78.7 µmol/L; Calcium 2.28 mmol/L; Albumin 37.9 g/L; Total Protein 6.5 g/dL; Glucose 11.7 mmol/L.
- Day 266 (ECOG 0): M Protein 1.04 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 3.63 g/L; Immunoglobulin A 6.73 g/L; Immunoglobulin M 0.414 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.93 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 58.3 µmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 10.2 mmol/L.
- Day 358 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.6 mg/dL; Immunoglobulin G 13.3 g/L; Immunoglobulin A 3.59 g/L; Immunoglobulin M 0.356 g/L; Beta 2 Microglobulin 2.56 µg/mL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.37 ×10⁹/L; Absolute Neutrophil 2.12 ×10⁹/L; Platelets 243 ×10⁹/L; Creatinine 68.1 µmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 10.3 mmol/L.
- Day 444 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.54 mg/dL; Immunoglobulin G 15.8 g/L; Immunoglobulin A 2.01 g/L; Immunoglobulin M 0.699 g/L; Beta 2 Microglobulin 2.25 µg/mL; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 6.32 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 84 µmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 7.6 g/dL; Glucose 5.39 mmol/L.
- Day 528 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.04 mg/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 1.92 g/L; Immunoglobulin M 0.525 g/L; Beta 2 Microglobulin 1.88 µg/mL; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 5.95 ×10⁹/L; Absolute Neutrophil 3.33 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 69.8 µmol/L; Calcium 2.33 mmol/L; Albumin 44.9 g/L; Total Protein 7.4 g/dL; Glucose 5.12 mmol/L.
- Day 584: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.29 mg/dL; Immunoglobulin G 14.9 g/L; Immunoglobulin A 2.01 g/L; Immunoglobulin M 0.564 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 4.8 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 5.24 ×10⁹/L; Absolute Neutrophil 2.86 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 69.8 µmol/L; Calcium 2.48 mmol/L; Albumin 44 g/L; Total Protein 7.1 g/dL; Glucose 6.44 mmol/L.
- Day 731 (ECOG 1): M Protein 0.95 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 52.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 9.43 g/L; Immunoglobulin A 6.72 g/L; Immunoglobulin M 0.34 g/L.
- Day 794 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.63 mg/dL; Immunoglobulin G 6.17 g/L; Immunoglobulin A 3.06 g/L; Immunoglobulin M 0.379 g/L; Beta 2 Microglobulin 1.84 µg/mL; Lactate Dehydrogenase 4.43 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 2.62 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 52 ×10⁹/L; Creatinine 68.1 µmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 5.12 mmol/L.

Other clinical attributes
- Day -12: Weight: 130 kg; Height: 190 cm.

Biospecimens (2 samples)
- Sample MMRF_2313_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_2313_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
